Somatic mutation profile of tumor specimen MP2PRT-PARMIB-TMP1-A (aliquot MP2PRT-PARMIB-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARMIB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,498 days).
Specimen MP2PRT-PARMIB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 281fcd78-6df6-4db0-8720-71e1bf6e4197.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMIB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMIB-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fd9546c-3009-4249-acdc-3bee2e8339fd

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Ins 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH18 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1343018328, COSV56916381, COSV56922528; called by muse, mutect2, varscan2
- DISP3 | c.3871G>A p.V1291M | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780615860, COSV53821587, COSV99608732; called by muse, mutect2, varscan2
- DYNC1H1 | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 97/301 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs1463717963; called by muse, mutect2, varscan2
- GRIA2 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 123/414 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs1463020369, COSV52393314; called by muse, mutect2, varscan2
- KCND3 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 27/501 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV56179663; called by muse, mutect2
- MICAL3 | c.2227G>A p.G743S | Missense Mutation (SNP) | VAF 27/450 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs1288556207, COSV99261381; called by muse, mutect2
- SDSL | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 36/330 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs747826836, COSV61885487; called by muse, mutect2, varscan2
- HEXD | c.1175G>A p.G392D (on ENST00000327949 / NM_001369487.1; = p.A422T on NM_173620.3) | Missense Mutation (SNP) | VAF 115/431 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCORL | c.3409A>T p.K1137* | Nonsense Mutation (SNP) | VAF 108/316 reads (34%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1858G>T p.E620* | Nonsense Mutation (SNP) | VAF 103/393 reads (26%) | called by muse, mutect2, varscan2
- SRPX2 | c.364T>C p.C122R | Missense Mutation (SNP) | VAF 19/439 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XBP1 | c.515dup p.L173Sfs*214 | Frame Shift Ins (INS) | VAF 112/409 reads (27%) | called by mutect2, pindel, varscan2
- ZRANB3 | c.769_771delinsCCATGCCCGGGGTCCTC p.L257Pfs*11 | Frame Shift Ins (INS) | VAF 56/289 reads (19%) | called by pindel, varscan2*
- FAM110B | c.930C>T p.S310= | Silent (SNP) | VAF 38/566 reads (7%) | catalogued as rs775422320, COSV64067127; called by muse, mutect2
- PKP2 | c.1914G>A p.Q638= | Silent (SNP) | VAF 30/297 reads (10%) | catalogued as COSV50730781; called by muse, mutect2
- PROM2 | c.2388C>T p.I796= | Silent (SNP) | VAF 48/352 reads (14%) | catalogued as COSV58297083; called by muse, mutect2, varscan2
- TG | c.7161C>T p.G2387= | Silent (SNP) | VAF 246/773 reads (32%) | catalogued as rs766209120, COSV55084864; called by muse, mutect2, varscan2
